Gene-level copy-number profile of tumor specimen AP-K24D-HU from APOLLO case AP-K24D, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3.
Specimen AP-K24D-HU: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d593a3ad-bc29-4089-9fc8-e58ab1cb0504.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-K24D-74 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/b3baed07-8608-4e3e-a0ea-8c54d4cc32bc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 1,856; copy number 2: 56,272; copy number 3: 115; copy number 4: 20; copy number 5: 32; copy number 6: 23; copy number 7: 64; copy number 8: 12.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:38,601,418–38,605,609, 1 gene: ABCD1P2.
- chr10:38,783,004–38,783,108, 1 gene: AL590623.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 131 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,906,695–77,649,964, 1 gene, copy number 6 (within-gene range 2–6): ROBO2.
- chr3:76,434,018–77,571,881, 4 genes, copy number 6: CAP1P1, RNU6-386P, VDAC1P7, AC133040.1.
- chr3:78,161,698–79,767,998, 7 genes, copy number 6 (within-gene range 3–6): RN7SKP61, AC108752.1, MRPS17P3, ROBO1, AC055731.1, RN7SL751P, AC117461.1.
- chr3:80,216,261–82,463,675, 17 genes, copy number 5: HNRNPA3P8, AC108740.1, AC068756.1, LINC02050, LINC02027, AC099542.2, AC099542.1, AC107302.2, AC107302.1, GBE1, RNU2-28P, SETP6, AC017015.1, AC017015.2, AC129807.1, LINC02008, RPL7AP23.
- chr3:84,958,989–86,991,149, 12 genes, copy number 5: CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3.
- chr12:65,645,992–69,274,358, 76 genes, copy number 7–8 (broad region; genes not listed).
- chr12:69,738,860–70,637,440, 14 genes, copy number 5–6: RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1.

Autosomal genes at a single copy (total copy number 1): 1,489. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
